Surgical pathology report (de-identified scan), TCGA case TCGA-24-1470, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Washington University, specimen TCGA-24-1470-01A (Primary Tumor).

[page 1 of 3]
SURGICAL PATHOLOGY REPORT
FINAL

Patient Name:

Address:

Gender:

DOB:

Service:

Location:

MRN:

Hospital #:

Patient Type:

Accession #:

Taken:

Received:

Accessioned:

Reported:

Physician(s):

DIAGNOSIS:

OVARIES, RIGHT AND LEFT, BILATERAL SALPINGO-OOPHORECTOMY

- ADENOCARCINOMA, MIXED EPITHELIAL TYPE, SEROUS (60%) AND TRANSITIONAL (40%)
- PARAOVARIAN ADHESIONS WITH ASSOCIATED CARCINOMA

FALLOPIAN TUBE, SIDE NOT SPECIFIED, SALPINGECTOMY

- NO HISTOPATHOLOGIC ABNORMALITY

OMENTUM, OMENTECTOMY

- METASTATIC ADENOCARCINOMA

RIGHT GUTTER, EXCISION

- METASTATIC ADENOCARCINOMA

RIGHT PELVIS, EXCISION

- METASTATIC ADENOCARCINOMA

***Rep

Intraoperative Consultation:

An intraoperative non-microscopic consultation was obtained and interpreted as: "Called to pick up 'left adnexa and right adnexa' consisting of bilateral unmarked ovaries. One ovary weighs 142 gm and measures 11 x 8 x 4.5 cm. The surface is disrupted and carpeted with tan papillary excrescences. Opened to show a solid, tan-brown, friable mass with no identifiable fallopian tube. The second ovary weighs 134 gm and measures 8 x 6.3 x 4 cm with a mostly smooth surface with focal papillary surface lesions. Opened to show a mostly solid, tan-yellow tumor with no residual ovarian parenchyma. Fimbriated end of the fallopian tube is identified and measures 2.5 x 0.3 cm. Portion of the first opened ovary frozen as 'FS1.'"

Ovary, right and left, excision

- "Poorly differentiated adenocarcinoma, favor Mullerian origin," by

[page 2 of 3]
Microscopic Description and Comment:

Microscopic examination substantiates the above cited diagnosis.

History:

The patient is a [REDACTED] with a history of breast cancer and a pelvic mass. The patient also has a CA-125 of 947. Operative procedure: Bilateral salpingo-oophorectomy and omentectomy.

Specimen(s) Received:

A: LEFT ADNEXAL, RIGHT ADNEXAL
B: OMENTUM
C: RIGHT GUTTER
D: RIGHT PELVIC

Gross Description:

The specimens are received in four formalin-filled containers each labeled [REDACTED]. The first container is labeled "left adnexal and right adnexal." It contains a white cassette labeled "FS1" that holds two pieces of tan-white tissue measuring 1.6 x 1.8 x 0.2 cm and 1.7 x 1.1 x 0.3 cm. Additionally in the container are two previously sectioned ovaries, the larger ovary measures approximately 9.5 x 8.0 x 3.5 cm. It has been previously sectioned to show a tan-brown friable mass as described in the intraoperative consult. There is no identifiable fallopian tube attached. The smaller ovary measures approximately 7.8 x 4.7 x 4.8 cm and has been previously sectioned to show a friable tan mass conceivably replacing the ovary as described in the intraoperative consultation. A small portion of attached fallopian tube is identified measuring 2.5 x 0.8 x 0.4 cm. Labeled A2 to A6 - larger ovary; A7 to A11 - smaller ovary; A12 - fallopian tube. [REDACTED]

The second container is labeled "omentum." It contains a 26.5 x 18.0 x 1.0 cm piece of yellow-tan omentum. Sections show no focal lesions. [REDACTED]

The third container is labeled "right gutter." It contains multiple fragments of tan tissue measuring 3.1 x 2.2 x 0.6 cm in aggregate. [REDACTED]

The fourth container is labeled "right pelvis." It contains a 2.2 x 1.8 x 0.8 cm piece of yellow-brown tissue. Sections show firm tan and white tissue. [REDACTED]

SYNOPTIC REPORTING FORM FOR MALIGNANT OVARIAN NEOPLASMS

HISTOPATHOLOGIC TYPE

The histologic diagnosis is mixed serous (60%) and transitional (40%)

TUMOR LOCATION

The locations of the primary tumor(s) are the right and left ovary (synchronous primary tumors)

HISTOLOGIC GRADE

The histologic grade is poorly differentiated (G2)

TUMOR INVASION

Tumor is identified on the ovarian surface(s)

Tumor does not invade the adjacent fallopian tube/peritubal soft tissue

[page 3 of 3]
TUMOR INVOLVEMENT

Tumor involvement of the pelvic peritoneum/soft tissue is present
Metastatic involvement of the omentum is present

TUMOR SIZE

The maximum dimension of tumor implants outside the true pelvis is microscopic

PRIMARY TUMOR (T)

Based on the above information, the primary tumor is classified as microscopic peritoneal metastasis beyond pelvis (T3a/IIIA)

REGIONAL LYMPH NODES (N)

The regional lymph nodes cannot be assessed

DISTANT METASTASIS (M)

The status of distant tumor site cannot be assessed

STAGE GROUPING

The Final AJCC/UICC/FIGO stage is T3a/N0/M0 (Stage IIIA)

The pathologic stage assigned here should be regarded as provisional, and may change after integration of clinical data not provided with this specimen.

Source: NCI Genomic Data Commons file e4d6de50-9210-4f4b-8fa6-e0e9647fe8a8 (TCGA-24-1470.F47EEFCF-F15D-42CB-8BD2-D0C252ECAFB3.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).